Gene-level copy-number profile of tumor specimen TCGA-AC-A62V-01A from TCGA case TCGA-AC-A62V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.6 years (21,389 days).
Specimen TCGA-AC-A62V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.938700b3-a62c-4bb7-886f-7b01dc98e33b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A62V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56508d59-8054-4ec4-aa73-c5d80052c592

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 337; copy number 2: 17,151; copy number 3: 26,186; copy number 4: 9,081; copy number 5: 1,196; copy number 6: 4,641; copy number 7: 52; copy number 8: 123; copy number 9: 245; copy number 10: 27; copy number 11: 142; copy number 12: 39; copy number 13: 198; copy number 14: 79; copy number 15: 18; copy number 16: 9; copy number 17: 48; copy number 18: 16; copy number 20: 35; copy number 21: 49; copy number 22: 8; copy number 23: 4; copy number 24: 33; copy number 25: 5; copy number 26: 9; copy number 30: 13; copy number 37: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A62V-01A-11D-A31T-01): tumor purity 0.66, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,223 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:183,186,238–185,520,986, 50 genes, copy number 8: LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2.
- chr1:191,823,432–193,106,114, 21 genes, copy number 8: LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2.
- chr1:193,136,503–193,136,583, 1 gene, copy number 8: MIR1278.
- chr4:7,965,310–10,749,586, 106 genes, copy number 8–13 (broad region; genes not listed).
- chr4:11,393,150–14,242,813, 29 genes, copy number 8 (within-gene range 2–8): HS3ST1, AC006230.1, AC025539.1, AC005699.1, LINC02360, AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1, AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1.
- chr4:14,690,710–17,634,105, 44 genes, copy number 9: SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28.
- chr4:40,810,027–41,216,714, 1 gene, copy number 7 (within-gene range 2–7): APBB2.
- chr4:40,990,154–41,114,045, 3 genes, copy number 7: RNA5SP160, RNU6-836P, RNU6-1195P.
- chr4:69,995,966–70,690,551, 19 genes, copy number 11–12: STATH, HTN3, HTN1, CSN1S2AP, PRR27, ODAM, FDCSP, CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN, AMBN, ENAM, AC009570.2, JCHAIN, UTP3.
- chr4:72,807,267–73,258,798, 6 genes, copy number 8–23: HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2.
- chr4:102,251,041–102,868,896, 16 genes, copy number 12–18 (within-gene range 2–18): SLC39A8, RN7SL728P, AC098487.1, AF213884.2, AF213884.3, NFKB1, MANBA, AF213884.1, LRRC37A15P, KRT8P46, AC018797.1, AC018797.2, UBE2D3, AC018797.3, UBE2D3-AS1, RNU7-151P.
- chr4:114,827,763–116,297,160, 8 genes, copy number 7 (within-gene range 2–7): NDST4, MRPS33P3, RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1.
- chr4:121,328,642–122,087,811, 14 genes, copy number 8: QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P.
- chr4:122,610,108–123,319,433, 11 genes, copy number 9 (within-gene range 6–9): IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5.
- chr4:125,676,718–127,623,803, 14 genes, copy number 9 (within-gene range 6–9): AC104664.1, NUP58P1, TMEM248P1, LINC02379, H3P15, AC097528.1, RBM48P1, Y_RNA, AC096773.1, AC093772.1, AC093772.2, AC097462.1, AC097462.2, AC097462.3.
- chr4:128,061,286–128,222,931, 1 gene, copy number 9 (within-gene range 6–9): LARP1B.
- chr4:128,155,389–129,377,504, 17 genes, copy number 9: FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2.
- chr14:25,267,064–27,295,516, 17 genes, copy number 7–18 (within-gene range 3–24): HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:34,541,044–38,371,338, 91 genes, copy number 7–21 (broad region; genes not listed).
- chr14:38,973,399–38,987,383, 2 genes, copy number 9: AL132994.2, Y_RNA.
- chr17:58,982,638–67,996,469, 276 genes, copy number 10–37 (within-gene range 6–37) (broad region; genes not listed).
- chr20:33,912,323–37,095,997, 113 genes, copy number 14–24 (within-gene range 2–24) (broad region; genes not listed).
- chr20:40,854,119–41,317,672, 9 genes, copy number 16 (within-gene range 4–16): RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81.
- chr20:46,345,980–49,188,367, 64 genes, copy number 8–20 (within-gene range 3–20) (broad region; genes not listed).
- chr20:52,192,159–54,269,542, 33 genes, copy number 7 (within-gene range 5–7): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:56,205,052–64,313,132, 257 genes, copy number 9–30 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 337. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
